Surgical pathology report (de-identified scan), TCGA case TCGA-46-3769, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-3769-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PROCEDURES:

BRON BRUSH RUL, BIOPSY

GROSS DESCRIPTION

Received for second opinion at the request of [REDACTED] are eight outside slides from The [REDACTED] [REDACTED] labeled as follows: [REDACTED] (1 slide), indicated by the accompanying pathology report to be right upper lobe transbronchial biopsies; [REDACTED] (two slides), indicated to be bronchial brushing right upper lobe; [REDACTED] (two slides), indicated to be post bronchoscopy sputum specimen; and [REDACTED] (three slides), indicated to be pooled bronchial washings. All specimens were obtained from the patient on [REDACTED] Slides and interpretive report to be returned following completion of studies.

FINAL DIAGNOSIS

LUNG, RIGHT UPPER LOBE (BIOPSY, [REDACTED] BRONCHIAL BRUSHINGS, [REDACTED] SPUTUM, [REDACTED]; WASHINGS, [REDACTED] [REDACTED] [REDACTED]):

RIGHT UPPER LOBE TRANSBRONCHIAL BIOPSY: POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA, FAVOR ADENOCARCINOMA.

BRONCHIAL BRUSHINGS: INCONCLUSIVE. ALTHOUGH FEW ATYPICAL CELLS ARE IDENTIFIED, THEY LIKELY REPRESENT REACTIVE PNEUMOCYTES AND ALVEOLAR MACROPHAGES. SPECIMEN IS NOT DIAGNOSTIC OF MALIGNANCY.

SPUTUM: NO MALIGNANCY IDENTIFIED. THE SPECIMEN IS COMPRISED OF ORAL MATERIAL ONLY AND IS NOT REPRESENTATIVE OF LOWER RESPIRATORY PATHOLOGY.

BRONCHIAL WASHINGS: NO MALIGNANCY IDENTIFIED. THE SPECIMEN IS NOT DIAGNOSTIC, WITH BLOOD AND ACUTE INFLAMMATION ONLY.

[REDACTED]

[REDACTED]

[page 2 of 7]
REASON FOR VISIT: LUNG CANCER

SLIDES:

ORDERED: 88304/2, 88305/5, 88309, 88311/2, 88331/2, 88342/2, LEVEL III - GRO/2,
LEVEL IV - GROS/5, LEVEL VI - GROS, DECALCIFICATION/2, PATHOLOGY CONSU/2,
IMMUNOPEROXIDAS/2, SURGICAL SPECIM

COMMENTS:

TISSUES:

- A. LYMPH NODE
- B. CHEST WALL
- C. LUNG-RIGHT UPPER LOBE
- D. RIB. - 5TH
- E. RIB. - 4TH
- F. LUNG, NOS - TOP OF SUPERIOR SEGMENT
- G. LYMPH NODE
- H. LYMPH NODE

Edited by:

CODES: P88304 - 88304
P88305 - 88305
P88309 - 88309
P88311 - 88311
P88331 - 88331
D50175 - RESECTION
88304TC - LEVEL III - GRO
88305TC - LEVEL IV - GROS
88309TC - LEVEL VI - GROS
88311TC - DECALCIFICATION
88331TC - PATHOLOGY CONSU
88342TC - IMMUNOPEROXIDAS
1 - SURGICAL SPECIM
TY2150 - CHEST
T08000 - LYMPH NODE
T28000 - LU
T10350 - RIB.
T28200|M80414 - RT UP LOBE LUNG|NON SMALL CELL

Continued on next page ...

[page 3 of 7]
ICD CODES: 162.3 - MAL NEO UPPER LOBE LUNG

MARKERS: 88304, 88304TC, 88305, 88305TC, 88309, 88309TC, 88311, DECAL, 88331,
PATH CONSULT FS, IMMUNOPEROXIDASE, RES, SURGICAL SPECIMEN

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: ADENOCARCINOMA, UPPER RIGHT LOBE LUNG CA

FINAL DIAGNOSIS

- A. LYMPH NODE, LEVEL 9R, EXCISION:
- TWO LYMPH NODES, NEGATIVE FOR TUMOR.
- B. RIGHT POSTERIOR SUPERIOR CHEST WALL PLAQUE, EXCISION:
- METASTATIC NON-SMALL CELL CARCINOMA.
- TUMOR IS PRESENT AT THE CAUTERIZED EDGES OF THE SPECIMEN.
- C. LUNG, RIGHT UPPER LOBE, LOBECTOMY:

Continued on next page ...

[page 4 of 7]
FINAL DIAGNOSIS

(Continued)

- POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA WITH SQUAMOUS FEATURES. SEE SYNOPTIC REPORT.

D. NECK OF 5TH RIB, RESECTION:

- BENIGN BONE.

E. 4TH RIB, RESECTION:

- BENIGN BONE.

F. TIP OF SUPERIOR SEGMENT, RESECTION:

- SEGMENT OF BENIGN LUNG, PLEURAL ADHESIONS, FOCAL CHRONIC INFLAMMATION, AND EMPHYSEMATOUS CHANGE.
- NO MALIGNANCY IS NOTED.

G. LYMPH NODE, RIGHT TRACHEOBRONCHIAL ANGLE, EXCISION:

- BENIGN LYMPH NODE (0/1).

H. LYMPH NODE, RIGHT LOBAR UPPER, EXCISION:

- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

Unless otherwise specified, the performance characteristics of the immunoperoxidase stains performed here have been confirmed by the

A. The specimen is submitted fresh for frozen section as "level 9 R" and consists of two pink black 0.4 and 0.5 cm nodules. The smaller will be marked with black dye and the larger bisected. The specimen is submitted in toto; 3 (1) labeled FSP for frozen section.

FROZEN SECTION DIAGNOSIS 9R: Two lymph nodes, negative for tumor.

COMMENTS: Touch prep has been taken.

Continued on next page ...

[page 5 of 7]
GROSS DESCRIPTION

(Continued)

B. The specimen is submitted fresh for frozen section as "right posterior superior chest wall" and consists of three pink red glistening segments of apparent fibrous tissue ranging 2 x 1 x 0.4 cm to 2.4 x 1 x 0.4 cm. Sectioning is unremarkable. Representative sections are submitted, 3 (1) labeled "FSP" used for frozen section.

FROZEN SECTION DIAGNOSIS: Right superior chest wall plaque:
Metastatic carcinoma. [REDACTED]

C. The specimen is submitted fresh but not for frozen section as "right upper lobe" and consists of a 650 gram (formalin fixed), 16 x 14.5 x 7.3 cm lung lobectomy with an 11 x 9 cm diffusely firm tan white nodular area with focal areas of gray tan shaggy fibromembranous adhesions. The lobectomy is received with a stapled bronchial margin measuring 2.5 cm in diameter along with multiple stapled vascular margins measuring 0.5 cm in length x 1.2 cm in diameter to 0.6 cm in length x 2 cm in diameter, and three stapled margins measuring 3.5 to 4 cm in diameter. The stapled margins are removed and the underlying parenchyma inked black. The shaggy pleural surface overlying the firm area is inked blue. Sectioning reveals a 14.4 x 8.5 x 7 cm well circumscribed gray white mass with a diffusely friable pink tan centrally necrotic center which extends throughout the entire lobe grossly appearing to abut the blue inked outer pleural surface measuring 1 cm from the hilum and 1.3 cm from the closest stapled resection margin. The remaining uninvolved parenchyma is maroon to red, spongy, homogenous and grossly unremarkable. No other discrete masses or nodularities are grossly identified. At the hilum is a 0.5 cm in greatest dimension gray black lymph node which is submitted entirely intact. Also noted are multiple gray black to white matted lymph nodes within the previously described mass measuring 0.8 to 2.2 cm in greatest dimension. Representative sections of the matted lymph nodes are submitted.

Representative sections are submitted, multiple (10) as follows:

- 1: Vascular and bronchial margins submitted en face.
- 2-4: Mass with closest pleural surface including overlying fibromembranous shaggy soft tissue.
- 5 and 6: Mass with closest stapled margin and adjacent hilum.
- 7 and 8: Representative sections of the matted lymph nodes.
- 9: Uninvolved parenchyma pleural surface.
- 10: One possible hilar lymph node submitted intact.
- [REDACTED]

D. The specimen is submitted fresh as "neck of fifth rib" and consists of a segment of bone consistent with rib measuring 1.8 cm in length and 1.4 cm in diameter. A representative section is submitted, 1 (1) for decalcification.

Continued on next page ...

[page 6 of 7]
GROSS DESCRIPTION

(Continued)

E. The specimen is submitted fresh as "fourth rib" and consists of two segments of bone consistent with rib measuring 1.7 x 0.7 x 0.4 cm and 1.8 x 1.5 x 0.8 cm. A representative section is submitted, 1 (1) for decalcification.

F. The specimen is submitted fresh as "tip of superior segment" and consists of a wedge of pulmonary tissue measuring 4 x 0.9 x 0.6 cm with stapled surgical margin. The pleural surface is gray and slightly reticulated with deposits of black carbon pigment. The staple line is removed and the margin marked with black dye. Serial sectioning is unremarkable; submitted in toto, 7 (1).

G. The specimen is submitted fresh as "right tracheobronchial angle node" and consists of a gray 1 cm nodular segment of tissue bisected and submitted in toto, 2 (1).

H. The specimen is submitted fresh as "right lobar node upper" and consists of a gray moderately firm nodule bisected; submitted in toto, 2 (1).

PRIORITY

PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

RESECTION

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY

LATERALITY: RIGHT

TUMOR SITE: RIGHT UPPER LOBE

TUMOR SIZE: 14.4 CM

HISTOLOGIC TYPE: NON-SMALL CELL WITH SQUAMOUS FEATURES

HISTOLOGIC GRADE: 3 OF 4 (POORLY DIFFERENTIATED)

EXTENT OF INVASION: TUMOR INVADES AT LEAST THE VISCERAL PLEURA, TUMOR ALSO

Continued on next page ...

[page 7 of 7]
SYNOPTIC REPORT

(Continued)

INVOLVES CHEST WALL IN SEPARATELY SUBMITTED TISSUE (PART B).
EXTENTION TO PLEURA/OTHER STRUCTURES: TUMOR INVOLVES CHEST WALL IN
SEPARATELY SUBMITTED TISSUE (PART B)

MARGINS:

BRONCHIAL: UNINVOLVED

PARENCHYMAL: UNINVOLVED

VASCULAR: UNINVOLVED

DISTANCE TO PERTINENT MARGIN(S): 1 CM FROM THE HILAR MARGIN AND IS 0.2 CM
FROM THE SOFT TISSUE MARGIN ON LUNG LOBECTOMY SPECIMEN.

VENOUS INVASION: ABSENT

ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

N1 - # INVOLVED/# EXAMINED: 0/8+

N2 - # INVOLVED/#EXAMINED: 0/8+

N3 - # INVOLVED/# EXAMINED: N/A

OTHER PERTINENT FINDINGS:

- THE TUMOR IS POORLY DIFFERENTIATED SHOWING FEATURES CONSISTENT WITH SQUAMOUS DIFFERENTIATION (P63+, TTF-1-) AND SCATTERED ANAPLASTIC CELLS.
- THE TUMOR DOES NOT TO EXTEND TO THE SOFT TISSUE MARGIN ON THE LOBECTOMY SPECIMEN; HOWEVER, THERE IS A SEPARATELY SUBMITTED CHEST WALL TISSUE (SPECIMEN PART B) WHICH IS INVOLVED BY TUMOR. IT IS UNCLEAR WHETHER THE CHEST WALL TUMOR REPRESENTS DIRECT INVASION BY THE LUNG TUMOR OR A METASTASIS. CLINICAL AND RADIOLOGIC CORRELATION IS INDICATED.

pTNM STAGE: pT3 N0 MX

Unless otherwise specified, the performance characteristics of the immunoperoxidase stains performed here have been confirmed by the [REDACTED].

[REDACTED] These tests have not been cleared or approved by the U.S. Food and Drug Administration, although such approval is not necessary.

*** End of Report ***

Source: NCI Genomic Data Commons file 7a7f1764-94bb-47e9-8eba-d6ed1654a6fe (TCGA-46-3769.EDD4E055-6670-43A8-BA91-0B4AC766ABFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).